Somatic mutation profile of tumor specimen TCGA-YD-A9TA-06A (aliquot TCGA-YD-A9TA-06A-11D-A397-08) from TCGA case TCGA-YD-A9TA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.8 years (28,424 days).
Specimen TCGA-YD-A9TA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88f47b13-247c-4c6c-a6cc-bc32f08a428a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YD-A9TA-10A (Blood Derived Normal), aliquot TCGA-YD-A9TA-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de302a4c-15a8-4891-bad1-e54226bf5b92

The open-access MAF lists 4,004 somatic variants for this specimen: 2,578 protein-altering or splice-affecting, 1,309 silent, 117 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,375, Silent 1,309, Nonsense Mutation 116, Intron 46, Splice Region 37, RNA 37, Splice Site 31, Frame Shift Del 11, 3'UTR 11, 3'Flank 9, 5'Flank 8, 5'UTR 6.

Variants (750 of 4,004; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs72559734, CM1211848, CM981873, COSV100217473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs281875332, CM122510, CM151355, COSV100079766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.4684C>T p.Q1562* | Nonsense Mutation (SNP) | VAF 48/135 reads (36%) | catalogued as rs397507737, CM129027, COSV101204461; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.7978C>T p.R2660* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as rs147416429, CM128937; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GHR | c.281G>A p.W94* | Nonsense Mutation (SNP) | VAF 66/110 reads (60%) | catalogued as rs1060499692, COSV100051315; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 58/105 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2, varscan2
- MED23 | c.3988C>T p.R1330* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as rs527236036, CM156009, COSV51581744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 28/35 reads (80%) | catalogued as rs587783857, CM990868, COSV60334353, COSV60338346; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs121913630, CM004393, CM920493, COSV100806317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs121913638, CM941084, COSV62522864; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780296175, CM973034, COSV62353027; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 71/126 reads (56%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- PTPRT | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61964623; called by muse, varscan2
- SCO2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 77/95 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs80358232, CM992667, COSV99329636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 28/35 reads (80%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- A2ML1 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100229163; called by muse, mutect2, varscan2
- AADACL2 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV62930537; called by muse, varscan2
- AAR2 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as rs769340068, COSV100299366; called by muse, mutect2, varscan2
- AASS | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs1210884316, COSV100741838; called by muse, mutect2, varscan2
- ABAT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51627053, COSV99191049; called by muse, mutect2, varscan2
- ABCA13 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV70029615; called by muse, mutect2, varscan2
- ABCA13 | c.2797C>T p.L933F | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1382890720, COSV101330110; called by muse, mutect2, varscan2
- ABCA3 | c.5051C>T p.S1684L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs766677326, COSV100068830; called by muse, mutect2, varscan2
- ABCA7 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs749855698, COSV99566255; called by muse, mutect2, varscan2
- ABCA7 | c.2709G>T p.W903C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200408449, COSV99565436; called by muse, mutect2, varscan2
- ABCA7 | c.5455C>A p.P1819T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs769453184, CM157246, COSV99566265; called by muse, mutect2, varscan2
- ABCA8 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99286344; called by muse, mutect2, varscan2
- ABCB11 | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99792520; called by muse, mutect2, varscan2
- ABCC3 | c.2984G>A p.W995* | Nonsense Mutation (SNP) | VAF 38/43 reads (88%) | catalogued as rs748599112, COSV99559437; called by muse, mutect2, varscan2
- ABCC3 | c.3093G>A p.M1031I | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99559439; called by muse, mutect2, varscan2
- ABCC3 | c.4465G>A p.D1489N | Missense Mutation (SNP) | VAF 74/94 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53325585, COSV99559442; called by muse, mutect2, varscan2
- ABCC5 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV55588236, COSV55593054; called by muse, mutect2, varscan2
- ABCC6 | c.4249C>T p.L1417F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99229140; called by muse, mutect2, varscan2
- ABCC9 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV53961740, COSV99686289; called by muse, mutect2, varscan2
- ABCG4 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100266891; called by muse, mutect2, varscan2
- ABHD16A | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV65452616; called by muse, varscan2
- AC100868.1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99226400; called by muse, mutect2, varscan2
- AC126283.2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773085612, CM161603, COSV67098504; called by muse, mutect2, varscan2
- AC126283.2 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM086400, CM136036, COSV101143955, COSV67097792; called by muse, mutect2, varscan2
- ACAN | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs761696605, COSV100718653; called by muse, mutect2, varscan2
- ACAN | c.4639G>A p.G1547R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs368770768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.4835G>A p.G1612E | Missense Mutation (SNP) | VAF 84/127 reads (66%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.801); catalogued as COSV100718658; called by muse, mutect2, varscan2
- ACAN | c.6589G>A p.E2197K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs751604379, COSV100718660; called by muse, mutect2, varscan2
- ACD | c.1520C>T p.P507L (on ENST00000620338; = p.P418L on NM_022914.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs149418249, COSV99537867; called by muse, mutect2, varscan2
- ACIN1 | c.2846C>T p.P949L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV99399897; called by muse, mutect2, varscan2
- ACOT12 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100297042; called by muse, mutect2, varscan2
- ACOXL | c.1610C>T p.A537V (on ENST00000389811 / NM_001371254.1; = p.A507V on NM_001142807.4) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs760258913, COSV67733281; called by muse, mutect2, varscan2
- ACP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs782249244, COSV100984233; called by muse, mutect2, varscan2
- ACP7 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV58701142; called by muse, mutect2, varscan2
- ACSM2A | c.280G>A p.A94T (on ENST00000219054; = p.A15T on NM_001308169.2) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99525442; called by muse, mutect2, varscan2
- ACSM2A | c.1303G>A p.A435T (on ENST00000219054; = p.A356T on NM_001308169.2) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as COSV99525444; called by muse, mutect2, varscan2
- ACSM4 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1323625538, COSV101257234; called by muse, mutect2, varscan2
- ACTC1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1451590510, COSV99291972; called by muse, mutect2, varscan2
- ACTL6B | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1299588423, COSV99355635; called by muse, mutect2, varscan2
- ACTL6B | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99355639; called by muse, mutect2, varscan2
- ACTL6B | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99355642; called by muse, mutect2, varscan2
- ACTL7A | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV100453167; called by muse, mutect2, varscan2
- ACTN2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100856886; called by muse, mutect2, varscan2
- ACY3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs200546996, COSV99662910; called by muse, mutect2, varscan2
- ADAD2 | c.1544C>T p.P515L (on ENST00000315906 / NM_001145400.2; = p.P597L on NM_139174.4) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1447440987, COSV99235458; called by muse, mutect2, varscan2
- ADAM18 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55843571, COSV99695858; called by muse, mutect2, varscan2
- ADAM20 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56457247; called by muse, mutect2, varscan2
- ADAM22 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55977126; called by muse, mutect2, varscan2
- ADAM28 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV99739201; called by muse, mutect2, varscan2
- ADAM29 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs1051260494, COSV63669346; called by muse, mutect2, varscan2
- ADAM29 | c.2432C>T p.S811F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); catalogued as rs1158169627, COSV100822116; called by muse, mutect2, varscan2
- ADAM7 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99444378; called by muse, mutect2, varscan2
- ADAMTS12 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV100711333; called by muse, mutect2, varscan2
- ADAMTS12 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100711335; called by muse, mutect2, varscan2
- ADAMTS16 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99941969; called by muse, mutect2, varscan2
- ADAMTS18 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.326); catalogued as COSV99273478; called by muse, mutect2, varscan2
- ADAMTS20 | c.3950C>T p.S1317F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270963084, COSV101166343; called by muse, mutect2, varscan2
- ADAMTS20 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV101239723; called by muse, mutect2, varscan2
- ADAMTS6 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs112516821; called by muse, mutect2, varscan2
- ADAMTS6 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs778280146, COSV66858507; called by muse, mutect2, varscan2
- ADAMTS7 | c.3638G>A p.R1213K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs1054875990, COSV101183168; called by muse, mutect2, varscan2
- ADAMTS8 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1358812645, COSV99961232; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2990A>C p.H997P | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101001970; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2358G>A p.W786* | Nonsense Mutation (SNP) | VAF 48/116 reads (41%) | catalogued as COSV99647583; called by muse, mutect2, varscan2
- ADCY10 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1395683105, COSV100896959; called by muse, mutect2, varscan2
- ADCY5 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs1177992211, COSV100568000; called by muse, mutect2, varscan2
- ADCY6 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs1442691683, COSV57168564; called by muse, mutect2, varscan2
- ADCY6 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100326741; called by muse, mutect2, varscan2
- ADCY8 | c.3670C>T p.H1224Y | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV99653117; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV100416649; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs267601483, COSV58441747; called by muse, mutect2, varscan2
- ADD1 | c.1313A>G p.Q438R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs537655601, COSV99296694; called by muse, mutect2, varscan2
- ADGRA3 | c.861T>G p.D287E | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV99293473; called by muse, mutect2, varscan2
- ADGRB2 | c.4121C>T p.P1374L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99926560; called by muse, mutect2
- ADGRB3 | c.3670G>A p.D1224N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV99486049; called by muse, mutect2, varscan2
- ADGRE1 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs138193492; called by muse, mutect2, varscan2
- ADGRE1 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51674601; called by muse, mutect2
- ADGRE1 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51677198; called by muse, mutect2, varscan2
- ADGRE3 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); catalogued as COSV53728267, COSV99506430; called by muse, varscan2
- ADGRE3 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs563718426, COSV99506434; called by muse, varscan2
- ADGRF5 | c.3884C>T p.S1295F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99345985; called by muse, mutect2, varscan2
- ADGRF5 | c.2534C>T p.S845F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99345987; called by muse, mutect2, varscan2
- ADGRG4 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54962955; called by muse, mutect2, varscan2
- ADGRG4 | c.6511C>T p.P2171S | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99796024; called by muse, mutect2, varscan2
- ADGRL3 | c.1100G>A p.G367E (on ENST00000506720 / NM_001322402.2; = p.G299E on NM_015236.6) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101547265, COSV72265789; called by muse, mutect2
- ADGRL3 | c.2869C>T p.L957F (on ENST00000506720 / NM_001322402.2; = p.L889F on NM_015236.6) | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547266; called by muse, mutect2, varscan2
- ADGRL4 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1182626722, COSV66059088; called by muse, mutect2, varscan2
- ADGRV1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758626904, COSV67981148; called by muse, mutect2, varscan2
- ADGRV1 | c.4515T>G p.S1505R | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as COSV101316180; called by muse, mutect2, varscan2
- ADGRV1 | c.5480G>A p.G1827D | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as rs764833487, COSV101316181; called by muse, varscan2
- ADGRV1 | c.12403G>A p.G4135S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV101316182; called by muse, mutect2, varscan2
- ADGRV1 | c.12685C>T p.P4229S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV101316184; called by muse, mutect2
- ADH1C | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV72463418; called by muse, mutect2, varscan2
- ADNP2 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV100081020; called by muse, mutect2, varscan2
- AFF4 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99535145; called by muse, mutect2, varscan2
- AGBL1 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV101223683; called by muse, mutect2, varscan2
- AGBL1 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV66853029; called by muse, mutect2, varscan2
- AGL | c.3919C>T p.P1307S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54060706; called by muse, mutect2, varscan2
- AGMAT | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs757648420, COSV101011797; called by muse, mutect2, varscan2
- AGO3 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as rs767375430, COSV55798709; called by muse, mutect2, varscan2
- AGTR2 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs868939201, COSV64156480; called by muse, mutect2, varscan2
- AGTR2 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.51); PolyPhen benign (0.292); catalogued as COSV100903595; called by muse, mutect2, varscan2
- AGXT2 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | catalogued as COSV99183786; called by muse, mutect2, varscan2
- AHCY | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV54153272; called by muse, mutect2, varscan2
- AHNAK | c.9719C>T p.S3240L | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs151029065; called by muse, mutect2, varscan2
- AKAP6 | c.1839C>G p.H613Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); catalogued as COSV55214778, COSV99802297; called by muse, mutect2, varscan2
- AKAP9 | c.5299C>T p.L1767F (on ENST00000359028; = p.L1735F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1328671206, COSV100662656; called by muse, mutect2, varscan2
- AKAP9 | c.5935C>T p.R1979C (on ENST00000359028; = p.R1947C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62337737; called by muse, mutect2, varscan2
- AL049569.3 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as rs1557716247, COSV100454258; called by muse, mutect2, varscan2
- AL121899.2 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs375529969; called by muse, mutect2, varscan2
- ALDH3A1 | c.480+1G>T p.X160_splice | Splice Site (SNP) | VAF 38/49 reads (78%) | catalogued as rs1364566000, COSV56736607; called by muse, mutect2, varscan2
- ALDH3A1 | c.480G>A p.K160= | Splice Region (SNP) | VAF 40/51 reads (78%) | catalogued as rs770654987, COSV99855975; called by muse, mutect2, varscan2
- ALDH8A1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs140344994; called by muse, mutect2, varscan2
- ALG10 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762214045, COSV56791818; called by muse, mutect2, varscan2
- ALG2 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99445358, COSV99445611; called by muse, mutect2, varscan2
- ALG2 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198613280, COSV99445616; called by muse, mutect2, varscan2
- ALMS1 | c.4421C>T p.P1474L | Missense Mutation (SNP) | VAF 79/126 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs1225664658, COSV100043012; called by muse, mutect2, varscan2
- ALPK1 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs369974578; called by muse, mutect2, varscan2
- ALPK2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184186856, COSV100864540; called by muse, mutect2, varscan2
- ALS2 | c.4495C>T p.R1499C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs112869526, COSV99969650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBN | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100534406; called by muse, varscan2
- AMBN | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100534408, COSV59825365; called by muse, varscan2
- AMBP | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV54322603; called by muse, mutect2, varscan2
- AMHR2 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs766690921, COSV57685768; called by muse, mutect2, varscan2
- AMY2A | c.516C>T p.V172= | Splice Region (SNP) | VAF 78/123 reads (63%) | catalogued as COSV101340626; called by muse, mutect2, varscan2
- ANAPC5 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 89/114 reads (78%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV99946335; called by muse, mutect2, varscan2
- ANK1 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 85/114 reads (75%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as COSV55897520, COSV99225903; called by muse, mutect2, varscan2
- ANK1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99225905; called by muse, mutect2, varscan2
- ANK2 | c.6205C>T p.R2069C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs754572911, COSV52159875, COSV52189518; called by muse, mutect2, varscan2
- ANK2 | c.6820C>T p.R2274C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs140258681; called by muse, mutect2, varscan2
- ANK2 | c.6946C>G p.P2316A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100002704; called by muse, mutect2
- ANK2 | c.6947C>T p.P2316L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.053); catalogued as rs1370359468, COSV100002706, COSV52147375; called by muse, mutect2
- ANK2 | c.7964C>T p.S2655L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs373153154, COSV52147308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.9763C>T p.P3255S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs867013789, COSV99780936; called by muse, mutect2, varscan2
- ANK3 | c.9124G>A p.E3042K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as rs146205433; called by muse, mutect2, varscan2
- ANK3 | c.3104C>T p.P1035L (on ENST00000280772 / NM_001320874.2; = p.P169L on NM_001149.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780937; called by muse, mutect2, varscan2
- ANK3 | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55049069; called by muse, mutect2, varscan2
- ANKRD27 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1360294995, COSV100042967; called by muse, mutect2, varscan2
- ANKRD30A | c.1334G>A p.G445E (on ENST00000611781; = p.G389E on NM_052997.2) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV100653978; called by muse, mutect2, varscan2
- ANKRD30A | c.1521G>A p.M507I (on ENST00000611781; = p.M451I on NM_052997.2) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs564319804, COSV64614781; called by muse, mutect2, varscan2
- ANKRD30A | c.3148G>A p.E1050K (on ENST00000611781; = p.E994K on NM_052997.2) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1237785275, COSV64605238; called by muse, mutect2, varscan2
- ANKRD30A | c.3439C>T p.Q1147* (on ENST00000611781; = p.Q1091* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 39/132 reads (30%) | catalogued as rs1448044187, COSV100653980; called by muse, mutect2, varscan2
- ANKRD30A | c.3913G>A p.E1305K (on ENST00000611781; = p.E1249K on NM_052997.2) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs867764777, COSV64614680, COSV64619316; called by muse, mutect2, varscan2
- ANKRD33 | c.724C>T p.P242S (on ENST00000340970 / NM_001304459.2; = p.Y433= on NM_182608.4) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100001411; called by muse, mutect2, varscan2
- ANKRD33 | c.725C>T p.P242L (on ENST00000340970 / NM_001304459.2; = p.Q434* on NM_182608.4) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs763362546, COSV100001412; called by muse, mutect2, varscan2
- ANKRD40 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV99560562; called by muse, mutect2, varscan2
- ANKRD45 | c.497-1G>A p.X166_splice | Splice Site (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100322589; called by muse, mutect2, varscan2
- ANKRD46 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.995); catalogued as COSV100170149; called by muse, mutect2, varscan2
- ANKRD53 | c.601G>C p.G201R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99721468; called by muse, mutect2, varscan2
- ANO4 | c.2131G>A p.D711N (on ENST00000392977 / NM_001286615.2; = p.D676N on NM_178826.4) | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.879); catalogued as rs754705690, COSV54588684, COSV54592568; called by muse, mutect2, varscan2
- ANO4 | c.2747G>A p.R916Q (on ENST00000392977 / NM_001286615.2; = p.R881Q on NM_178826.4) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs267603265, COSV54611712; called by muse, mutect2, varscan2
- ANXA1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV99973997; called by muse, mutect2, varscan2
- ANXA13 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99146377; called by muse, mutect2, varscan2
- AOAH | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218988618, COSV51740141; called by muse, mutect2, varscan2
- AOAH | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99333214; called by muse, mutect2, varscan2
- AOC1 | c.580T>G p.S194A | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs1488548734, COSV100710858; called by muse, mutect2, varscan2
- AOC1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.209); catalogued as COSV100710859; called by muse, mutect2, varscan2
- AOPEP | c.1116C>T p.F372= | Splice Region (SNP) | VAF 33/135 reads (24%) | catalogued as COSV99468883; called by muse, mutect2, varscan2
- AP002512.3 | c.453G>T p.L151F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99688031; called by muse, mutect2, varscan2
- AP3B2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55609858, COSV99916151; called by muse, mutect2, varscan2
- AP4E1 | c.3050C>T p.A1017V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99956855; called by muse, mutect2, varscan2
- APBB2 | c.2167C>T p.P723S (on ENST00000295974 / NM_001166050.2; = p.P724S on NM_004307.2) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.047); catalogued as COSV99923569; called by muse, mutect2, varscan2
- APBB2 | c.1859C>T p.S620F (on ENST00000295974 / NM_001166050.2; = p.S621F on NM_004307.2) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745627935, COSV99923570; called by mutect2, varscan2
- APCDD1L | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.881); catalogued as rs1258008384, COSV64487013; called by muse, mutect2, varscan2
- APH1B | c.607-1G>C p.X203_splice | Splice Site (SNP) | VAF 31/78 reads (40%) | catalogued as COSV99971572; called by muse, mutect2, varscan2
- APOBEC3A | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV99970370; called by muse, mutect2, varscan2
- APOBEC3F | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 88/114 reads (77%) | SIFT tolerated (0.43); PolyPhen benign (0.052); catalogued as rs768209849, COSV100415229; called by muse, mutect2, varscan2
- APOH | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 61/77 reads (79%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV99235854; called by muse, mutect2, varscan2
- APOH | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as rs112244796, COSV52772010, COSV52772599; called by muse, mutect2, varscan2
- AQP2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1280344383, COSV99550872; called by muse, mutect2, varscan2
- ARAP2 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141950924, COSV58293960; called by muse, mutect2, varscan2
- ARHGAP10 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100331460; called by muse, mutect2, varscan2
- ARHGAP11A | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs201555862, COSV100276855; called by muse, mutect2, varscan2
- ARHGAP21 | c.2847+1G>A p.X949_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100256421; called by muse, mutect2, varscan2
- ARHGAP21 | c.2847G>A p.K949= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100256423; called by muse, mutect2, varscan2
- ARHGAP21 | c.2435G>A p.S812N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100256425; called by muse, mutect2, varscan2
- ARHGAP25 | c.1519C>T p.P507S (on ENST00000409202 / NM_001007231.3; = p.P499S on NM_014882.3) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.374); catalogued as COSV99771791; called by muse, mutect2, varscan2
- ARHGAP28 | c.1699C>A p.R567S (on ENST00000383472 / NM_001366230.1; = p.R408S on NM_001010000.3) | Missense Mutation (SNP) | VAF 127/194 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV51634353, COSV99151102; called by muse, varscan2
- ARHGAP30 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs759817018, COSV63519294; called by muse, varscan2
- ARHGAP30 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100920358; called by muse, varscan2
- ARHGAP30 | c.1881G>A p.W627* | Nonsense Mutation (SNP) | VAF 58/143 reads (41%) | catalogued as COSV63516197; called by muse, mutect2, varscan2
- ARHGAP35 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101351310; called by muse, mutect2, varscan2
- ARHGEF37 | c.410A>T p.K137M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100382206; called by muse, mutect2, varscan2
- ARID1B | c.5264C>T p.P1755L | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs142466273; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARID3C | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV99426966; called by muse, mutect2, varscan2
- ARL5A | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs1230416518, COSV99706707; called by muse, mutect2, varscan2
- ARMC4 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV100537106; called by muse, mutect2, varscan2
- ARMH4 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV99958572; called by muse, mutect2, varscan2
- ARRDC5 | c.736G>A p.D246N (on ENST00000381781; = p.D232N on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV101108216; called by muse, mutect2, varscan2
- ARSH | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV101139925; called by muse, mutect2, varscan2
- ARSJ | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59538947; called by muse, mutect2, varscan2
- ASAP1 | c.2729C>T p.S910F | Missense Mutation (SNP) | VAF 91/178 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100727506; called by muse, mutect2, varscan2
- ASAP1 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs933075970, COSV63048662; called by muse, mutect2, varscan2
- ASB7 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 38/50 reads (76%) | catalogued as COSV100235247; called by muse, mutect2, varscan2
- ASNS | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.281); catalogued as COSV99446502; called by muse, mutect2, varscan2
- ASPA | c.83T>A p.V28E | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99279334; called by muse, mutect2, varscan2
- ASXL3 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV99325618; called by muse, mutect2, varscan2
- ASXL3 | c.5077C>T p.P1693S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV52478425, COSV99325619; called by muse, mutect2, varscan2
- ASXL3 | c.5078C>T p.P1693L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1272616032, COSV99325624; called by muse, mutect2, varscan2
- ATAD2 | c.3260C>T p.A1087V | Missense Mutation (SNP) | VAF 70/122 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs1330095007, COSV99784970; called by muse, mutect2, varscan2
- ATG4B | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV100728714; called by muse, mutect2
- ATMIN | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs199541307, COSV55145212; called by muse, mutect2, varscan2
- ATN1 | c.2622dup p.Y875Lfs*5 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | catalogued as rs782176238; called by mutect2, pindel, varscan2
- ATP13A4 | c.3176G>A p.G1059E | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61328945; called by muse, mutect2, varscan2
- ATP13A4 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as rs918287872, COSV55068189; called by muse, mutect2, varscan2
- ATP13A4 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.145); catalogued as COSV99794850; called by muse, mutect2, varscan2
- ATP4A | c.2179G>A p.G727R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749693841, COSV52870799; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs199698721, COSV57749267; called by muse, mutect2, varscan2
- ATP6V0A4 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100023301; called by muse, mutect2, varscan2
- ATP6V1G3 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99810959; called by muse, mutect2, varscan2
- ATP7B | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.116); catalogued as COSV54445782; called by muse, mutect2, varscan2
- ATP8A1 | c.2266G>A p.G756R | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs1178625493, COSV100046656; called by muse, mutect2, varscan2
- ATP8A1 | c.1496T>A p.I499N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100046660; called by muse, mutect2, varscan2
- ATP8B3 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs767359352, COSV100034666; called by muse, mutect2, varscan2
- ATRNL1 | c.3793G>C p.E1265Q | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.575); catalogued as COSV58079062, COSV58110468; called by muse, mutect2, varscan2
- AXL | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs201596308, COSV56571583; called by muse, mutect2, varscan2
- AXL | c.1424G>A p.R475Q (on ENST00000301178 / NM_021913.5; = p.R466Q on NM_001699.6) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs750167315, COSV56568456; called by muse, mutect2, varscan2
- B3GALT5 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100563439; called by muse, mutect2, varscan2
- BAG6 | c.2390C>T p.S797F (on ENST00000676571; = p.S750F on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV99277293; called by muse, mutect2, varscan2
- BAHD1 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV101346777; called by muse, mutect2, varscan2
- BAIAP2 | c.773T>G p.L258R | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV100348465; called by muse, mutect2, varscan2
- BANK1 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV100536576, COSV59842374; called by muse, mutect2, varscan2
- BBS2 | c.1662C>T p.I554= | Splice Region (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99802597; called by muse, mutect2, varscan2
- BBS9 | c.1588C>T p.P530S (on ENST00000242067 / NM_001348036.1; = p.P490S on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1362054920, COSV99629137; called by muse, mutect2, varscan2
- BBX | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs762447541, COSV100361947; called by muse, mutect2, varscan2
- BCL11A | c.952C>T p.P318S (on ENST00000335712 / NM_001365609.1; = p.P352S on NM_018014.4) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.685); catalogued as COSV100186007; called by muse, mutect2, varscan2
- BCL11A | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV59632860; called by muse, mutect2
- BCLAF1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62140436; called by muse, mutect2, varscan2
- BCO1 | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.92); catalogued as COSV99258297; called by muse, mutect2, varscan2
- BCR | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs770723511, COSV100006729; called by muse, mutect2, varscan2
- BCR | c.3075C>T p.I1025= | Splice Region (SNP) | VAF 45/66 reads (68%) | catalogued as rs771658233, COSV59936558; called by muse, mutect2, varscan2
- BEND3 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs1554231316, COSV100944639; called by muse, mutect2, varscan2
- BFSP2 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as COSV100183830; called by muse, mutect2, varscan2
- BIN2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1294070066, COSV99909543, COSV99909562; called by muse, mutect2, varscan2
- BIRC6 | c.3935C>T p.S1312F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs749093978, COSV101428468; called by muse, mutect2, varscan2
- BIRC6 | c.10837C>T p.L3613F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101428469; called by muse, mutect2, varscan2
- BLNK | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs781793117, COSV99814060; called by muse, mutect2, varscan2
- BLVRA | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99646045; called by muse, mutect2, varscan2
- BMP2K | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as rs773671159, COSV100621836, COSV58599634; called by muse, mutect2, varscan2
- BMP5 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.034); catalogued as COSV100896129, COSV100896256; called by muse, varscan2
- BMP5 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753416646, COSV63704996; called by muse, varscan2
- BMPER | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1562734322, COSV99780020; called by muse, mutect2, varscan2
- BMS1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996755; called by muse, mutect2, varscan2
- BNC1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61756657; called by muse, mutect2, varscan2
- BOLL | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV99987241; called by muse, mutect2, varscan2
- BPIFB4 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1350285803, COSV100971580; called by muse, mutect2, varscan2
- BPIFB4 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971582; called by muse, mutect2, varscan2
- BRCA1 | c.5575C>T p.P1859S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1555574342, COSV100524652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.3401C>T p.P1134L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV99651028; called by muse, mutect2, varscan2
- BRDT | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.69); PolyPhen benign (0.111); catalogued as COSV100746507; called by muse, mutect2, varscan2
- BRINP2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100838080; called by muse, mutect2, varscan2
- BRINP3 | c.1679C>T p.T560I | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV100819094, COSV66522423; called by muse, mutect2, varscan2
- BRWD3 | c.3526C>T p.P1176S | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956276, COSV64753766; called by muse, mutect2, varscan2
- BSN | c.9889G>A p.D3297N | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs267599873, COSV56518683; called by muse, mutect2, varscan2
- BTBD7 | c.3100C>T p.P1034S | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100597993; called by muse, mutect2, varscan2
- BTC | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs150393238, COSV67547383; called by muse, mutect2, varscan2
- BUB1 | c.3127C>T p.H1043Y | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV100241431; called by muse, mutect2, varscan2
- BUB1B | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as rs200884355, COSV99807071; called by muse, mutect2, varscan2
- C10orf120 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs267602400, COSV100271561, COSV61491830; called by muse, mutect2, varscan2
- C12orf50 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53894750, COSV53894777; called by muse, mutect2, varscan2
- C14orf39 | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100407844, COSV58780571; called by muse, mutect2, varscan2
- C15orf39 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV100641403, COSV62296098; called by muse, mutect2, varscan2
- C1QTNF3 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1255813346, COSV51468465, COSV99180691; called by muse, mutect2, varscan2
- C1QTNF9B | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1226647528, COSV101158588; called by muse, mutect2, varscan2
- C1R | c.1511C>T p.A504V (on ENST00000536053 / NM_001354346.2; = p.A490V on NM_001733.7) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.782); catalogued as COSV101605631; called by muse, mutect2, varscan2
- C1S | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100196673; called by muse, mutect2, varscan2
- C1orf127 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1198518452, COSV65438099; called by muse, mutect2, varscan2
- C1orf131 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV100009872; called by muse, mutect2, varscan2
- C1orf74 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs776454243, COSV99162139; called by muse, mutect2, varscan2
- C2 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147553278; called by muse, mutect2, varscan2
- C20orf194 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52702838; called by muse, mutect2, varscan2
- C2orf16 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV101284403; called by muse, mutect2, varscan2
- C2orf78 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV101281003; called by muse, mutect2, varscan2
- C3 | c.4846C>T p.P1616S | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV55576789; called by muse, mutect2, varscan2
- C3 | c.4280G>A p.R1427K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV55582537; called by muse, mutect2, varscan2
- C3 | c.3865C>T p.H1289Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as rs868565543, COSV99836915; called by muse, mutect2, varscan2
- C3 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868610191, COSV99836922; called by muse, mutect2, varscan2
- C3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.04); catalogued as rs1568226131, COSV99836925; called by muse, mutect2, varscan2
- C3orf20 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); catalogued as COSV99514275; called by muse, mutect2, varscan2
- C4orf17 | c.837-1G>C p.X279_splice | Splice Site (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100431015; called by muse, mutect2, varscan2
- C4orf50 | c.154G>A p.E52K (on ENST00000324058; = p.E1284K on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1407140733, COSV100135610, COSV100136023; called by muse, mutect2, varscan2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 80/103 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- C5AR1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1431302842, COSV100754043; called by muse, mutect2, varscan2
- C6orf58 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100314972; called by muse, mutect2, varscan2
- C7orf57 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.503); catalogued as rs1279754873, COSV100817302; called by muse, varscan2
- C9 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99662271; called by muse, mutect2, varscan2
- C9orf152 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 133/160 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766025731, COSV101272391; called by muse, mutect2, varscan2
- C9orf153 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs757701675, COSV59250541, COSV59252014; called by muse, mutect2, varscan2
- CACNA1D | c.4780C>T p.P1594S (on ENST00000350061 / NM_001128840.3; = p.P1614S on NM_000720.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55439786; called by muse, mutect2, varscan2
- CACNA1E | c.1440G>A p.W480* | Nonsense Mutation (SNP) | VAF 32/92 reads (35%) | catalogued as COSV100701265; called by muse, mutect2, varscan2
- CACNA1E | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1199352932, COSV100703934; called by muse, mutect2
- CACNA1E | c.5914G>A p.E1972K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV100703938; called by muse, mutect2, varscan2
- CACNA1G | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61735415; called by muse, mutect2, varscan2
- CACNA1G | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs1416268487, COSV100662158; called by muse, varscan2
- CACNA1G | c.6358C>T p.P2120S | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV100662159; called by muse, mutect2, varscan2
- CACNA1I | c.5438C>T p.S1813F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1343863097, COSV100360873; called by muse, mutect2, varscan2
- CACNA1S | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1361352939, COSV62938188, COSV62941112; called by muse, mutect2, varscan2
- CACNA2D3 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55582316; called by muse, mutect2, varscan2
- CACNA2D3 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320733630, COSV99875111; called by muse, mutect2, varscan2
- CADPS2 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.287); catalogued as rs1234392022, COSV100464154; called by muse, mutect2, varscan2
- CADPS2 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs773480913, COSV57351573; called by muse, mutect2, varscan2
- CAGE1 | c.697C>T p.P233S (on ENST00000512086; = p.P97S on NM_205864.3) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99699885; called by muse, mutect2, varscan2
- CALCR | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as COSV100810669, COSV64007804; called by muse, mutect2, varscan2
- CALHM5 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs1331179547, COSV62068696; called by muse, mutect2, varscan2
- CALHM6 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 67/151 reads (44%) | catalogued as COSV63991584; called by muse, mutect2, varscan2
- CAMK1D | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs565781008, COSV66619654; called by muse, mutect2, varscan2
- CAMK4 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.336); catalogued as COSV56661893; called by muse, mutect2, varscan2
- CAMTA1 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 124/191 reads (65%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.365); catalogued as COSV100351407; called by muse, mutect2, varscan2
- CAMTA1 | c.3175C>T p.H1059Y | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57933282; called by muse, mutect2, varscan2
- CANX | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99910551; called by muse, mutect2, varscan2
- CAPN13 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as COSV54429960, COSV99700242; called by muse, mutect2, varscan2
- CARD10 | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 42/55 reads (76%) | catalogued as COSV52661181, COSV99325171; called by muse, mutect2, varscan2
- CARD11 | c.2890A>C p.S964R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV101210756, COSV101210783; called by muse, mutect2, varscan2
- CARD11 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 84/159 reads (53%) | catalogued as COSV67803321; called by muse, mutect2, varscan2
- CASD1 | c.1534T>C p.Y512H | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51976194; called by muse, mutect2, varscan2
- CASP8AP2 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99387245; called by muse, mutect2, varscan2
- CASR | c.1414G>A p.G472R (on ENST00000490131; = p.G549R on NM_000388.4) | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM983818, COSV99949202; called by muse, mutect2, varscan2
- CASR | c.1923G>A p.W641* (on ENST00000490131; = p.W718* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as CM055920, COSV99949205; called by muse, mutect2, varscan2
- CASS4 | c.2071C>T p.H691Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV64387790, COSV64388208; called by muse, mutect2, varscan2
- CASZ1 | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs771060379, COSV100681321, COSV100681755; called by muse, mutect2, varscan2
- CATSPER4 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 58/84 reads (69%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs774394198, COSV100128451; called by muse, mutect2, varscan2
- CAVIN1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 127/169 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1338573396, COSV63811902; called by muse, mutect2, varscan2
- CBLB | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV99913817; called by muse, mutect2, varscan2
- CBLB | c.1204-1G>A p.X402_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV51423875, COSV99913819; called by muse, mutect2, varscan2
- CBLN4 | c.294C>T p.I98= | Splice Region (SNP) | VAF 30/57 reads (53%) | catalogued as COSV50353160; called by muse, mutect2, varscan2
- CBR1 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99289535; called by muse, mutect2, varscan2
- CCDC116 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201966964, COSV53038221; called by muse, mutect2, varscan2
- CCDC14 | c.952C>T p.R318* (on ENST00000488653; = p.R270* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 46/184 reads (25%) | catalogued as rs776294290, COSV59945809; called by muse, mutect2
- CCDC141 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs757376410, COSV55369931, COSV55371854; called by muse, mutect2, varscan2
- CCDC148 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV51754023, COSV51760035; called by muse, mutect2, varscan2
- CCDC158 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV66356826; called by muse, mutect2, varscan2
- CCDC178 | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV55759924, COSV55760328; called by muse, mutect2, varscan2
- CCDC191 | c.139A>C p.K47Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.106); catalogued as COSV99878484; called by muse, mutect2, varscan2
- CCDC33 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV99166080; called by muse, mutect2, varscan2
- CCDC54 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99660268; called by muse, mutect2, varscan2
- CCDC68 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100491899; called by muse, mutect2, varscan2
- CCDC68 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV100491902; called by muse, mutect2, varscan2
- CCDC7 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99511723; called by muse, mutect2, varscan2
- CCDC7 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.813); catalogued as rs1307879443, COSV100178754; called by muse, mutect2, varscan2
- CCDC71 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 47/83 reads (57%) | catalogued as COSV58909749; called by muse, mutect2, varscan2
- CCDC74A | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99723798; called by muse, mutect2, varscan2
- CCDC81 | c.1096G>A p.A366T (on ENST00000445632 / NM_001156474.2; = p.A276T on NM_021827.4) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99564560; called by muse, mutect2, varscan2
- CCDC88C | c.3938C>T p.S1313L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs1319502533, COSV101105930; called by muse, mutect2, varscan2
- CCDC88C | c.3344C>T p.T1115I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101105936; called by muse, mutect2, varscan2
- CCDC97 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99523792; called by muse, mutect2, varscan2
- CCDC9B | c.1547G>A p.R516K | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV101233535; called by muse, mutect2, varscan2
- CCER1 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1448590174, COSV100727095; called by muse, mutect2, varscan2
- CCIN | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs762886830, COSV58726121; called by muse, mutect2, varscan2
- CCKAR | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55163144, COSV55163439; called by muse, mutect2, varscan2
- CCM2L | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52951636; called by muse, mutect2, varscan2
- CCND2 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs776036883, COSV54225096; called by muse, mutect2, varscan2
- CCNF | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as rs752075387, COSV99563854; called by muse, mutect2, varscan2
- CCNJ | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99796298; called by muse, mutect2, varscan2
- CCPG1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747664502, COSV100197272; called by muse, mutect2, varscan2
- CCR1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99946753; called by muse, mutect2, varscan2
- CCR5 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV99433524; called by muse, mutect2, varscan2
- CCR5 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV99433528; called by muse, mutect2, varscan2
- CCR9 | c.571G>A p.E191K (on ENST00000357632 / NM_031200.3; = p.E179K on NM_006641.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV62940189; called by muse, mutect2, varscan2
- CCSER2 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs1419747706, COSV99826218; called by muse, mutect2, varscan2
- CCT6A | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs758352451, COSV51904849, COSV99303596; called by muse, mutect2, varscan2
- CCT8L2 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 75/97 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100742897; called by muse, mutect2, varscan2
- CD163 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as COSV63129495; called by muse, mutect2, varscan2
- CD163 | c.2369G>A p.G790E | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778094768, COSV63130873; called by muse, mutect2, varscan2
- CD163 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs267603679, COSV63132851; called by muse, mutect2, varscan2
- CD1B | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 146/329 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV100939259; called by muse, mutect2, varscan2
- CD2 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV65644387; called by muse, mutect2, varscan2
- CD209 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV52650651; called by muse, mutect2, varscan2
- CD244 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100458710; called by muse, mutect2, varscan2
- CD248 | c.1801T>C p.S601P | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1350716591, COSV60937279; called by muse, mutect2, varscan2
- CD84 | c.910G>A p.V304M (on ENST00000311224 / NM_001184879.2; = p.V287M on NM_003874.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as rs1375046614, COSV100246166; called by muse, mutect2, varscan2
- CD8B | c.625C>T p.Q209* (on ENST00000331469 / NM_172213.4; = p.Q179* on NM_172102.4) | Nonsense Mutation (SNP) | VAF 72/177 reads (41%) | catalogued as COSV100514615; called by muse, mutect2, varscan2
- CDC25C | c.834C>G p.N278K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV100086797; called by muse, mutect2, varscan2
- CDCP1 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV99944171; called by muse, mutect2, varscan2
- CDCP1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV99944172; called by muse, mutect2, varscan2
- CDH11 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.933); catalogued as COSV99219093; called by muse, mutect2
- CDH16 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs1317400494, COSV100234004; called by muse, mutect2, varscan2
- CDH18 | c.1530T>A p.S510R | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV99936572; called by muse, mutect2, varscan2
- CDH18 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV56898154; called by muse, mutect2, varscan2
- CDH2 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs150313483; called by muse, mutect2, varscan2
- CDH6 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54067368, COSV54073060; called by muse, mutect2, varscan2
- CDH6 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs138589959, COSV54074759; called by muse, mutect2, varscan2
- CDH8 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100182445, COSV100182985; called by muse, mutect2, varscan2
- CDH9 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50452461; called by muse, varscan2
- CDH9 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs867964392, COSV50259663; called by muse, varscan2
- CDHR1 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs547812313, COSV100259143; called by muse, mutect2, varscan2
- CDK11B | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1364199097, COSV58339727; called by muse, mutect2, varscan2
- CDK14 | c.1282G>T p.E428* (on ENST00000380050 / NM_001287135.2; = p.E410* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV56031455, COSV99726069; called by muse, mutect2, varscan2
- CDK19 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs761138528, COSV100098801; called by muse, mutect2, varscan2
- CDSN | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.019); catalogued as rs560607707, COSV99457015; called by muse, mutect2, varscan2
- CEACAM18 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV67284093; called by muse, mutect2, varscan2
- CEACAM8 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV54990962, COSV99747701; called by muse, varscan2
- CECR2 | c.3247C>T p.P1083S (on ENST00000342247 / NM_001290047.2; = p.P899S on NM_001290046.1) | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as COSV99378545; called by muse, mutect2, varscan2
- CELF3 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1222158755, COSV99310112, COSV99310446; called by muse, mutect2, varscan2
- CELF3 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs767180416, COSV99310452; called by muse, varscan2
- CELSR3 | c.4096C>T p.R1366C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs755218848, COSV99374160; called by muse, mutect2, varscan2
- CENPI | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV99515580; called by muse, mutect2, varscan2
- CENPS-CORT | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.082); catalogued as COSV100259229; called by muse, mutect2, varscan2
- CEP135 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV57258375, COSV99954673; called by muse, mutect2, varscan2
- CEP152 | c.1306C>A p.H436N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100358963; called by muse, mutect2, varscan2
- CEP20 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | catalogued as rs574018864, COSV99739925; called by muse, mutect2, varscan2
- CES3 | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 114/242 reads (47%) | catalogued as rs1390777243, COSV57594015; called by muse, mutect2, varscan2
- CES5A | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778201783, COSV99307751; called by muse, mutect2, varscan2
- CFAP206 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs377549577, COSV51535435; called by muse, mutect2, varscan2
- CFAP43 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.175); catalogued as rs1348848635, COSV53377669; called by muse, mutect2, varscan2
- CFAP46 | c.5527G>A p.E1843K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.542); catalogued as COSV54154760; called by muse, mutect2, varscan2
- CFAP54 | c.8261C>T p.S2754L | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs568368996, COSV61572344; called by muse, mutect2, varscan2
- CFAP57 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.465); catalogued as rs200345375, COSV100993996; called by muse, mutect2, varscan2
- CFAP58 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs775995835, COSV100459016; called by muse, mutect2, varscan2
- CFAP65 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404439204, COSV100445447; called by muse, mutect2, varscan2
- CFAP65 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1481753301, COSV55391461; called by muse, mutect2, varscan2
- CFAP69 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV100290302; called by muse, mutect2, varscan2
- CFAP91 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV56341421, COSV99847287; called by muse, mutect2, varscan2
- CFH | c.2636G>A p.G879E | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866405501, COSV100809856; called by muse, mutect2, varscan2
- CFHR5 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as COSV99889235; called by muse, mutect2, varscan2
- CGN | c.3022C>A p.Q1008K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99642540; called by muse, mutect2
- CHD5 | c.4990G>A p.E1664K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs1476026134, COSV52413242; called by muse, mutect2, varscan2
- CHD5 | c.1976T>C p.L659P | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as COSV99314233; called by muse, mutect2, varscan2
- CHD6 | c.6032C>T p.P2011L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100951194; called by muse, mutect2, varscan2
- CHD9 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 42/77 reads (55%) | catalogued as COSV101272157; called by muse, mutect2, varscan2
- CHGB | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66759868; called by muse, mutect2, varscan2
- CHI3L2 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100869301; called by muse, mutect2, varscan2
- CHI3L2 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63874122; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, mutect2, varscan2
- CHL1 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56605835; called by muse, mutect2, varscan2
- CHL1 | c.2161C>T p.Q721* (on ENST00000397491 / NM_001253387.1; = p.Q737* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 58/108 reads (54%) | catalogued as COSV99851643; called by muse, mutect2, varscan2
- CHL1 | c.3350A>C p.E1117A (on ENST00000397491 / NM_001253387.1; = p.E1133A on NM_006614.4) | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851645; called by muse, mutect2, varscan2
- CHMP7 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs757496234, COSV100500649; called by muse, mutect2, varscan2
- CHN1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753725678, COSV99789303; called by muse, varscan2
- CHST1 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.875); catalogued as COSV100346368; called by muse, mutect2, varscan2
- CHST11 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100359675; called by muse, mutect2, varscan2
- CHTF18 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99135892; called by muse, mutect2, varscan2
- CHTF18 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1230532843, COSV99135894; called by muse, mutect2, varscan2
- CIITA | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100162299; called by muse, mutect2, varscan2
- CILP2 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1304518526, COSV99364946; called by muse, mutect2
- CILP2 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs931769399, COSV99364948; called by muse, mutect2, varscan2
- CLASP2 | c.3548C>T p.P1183L (on ENST00000359576; = p.P1182L on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100223823; called by muse, mutect2
- CLCA3P | n.178G>A | Splice Region (SNP) | VAF 13/33 reads (39%) | catalogued as rs1333843366; called by muse, mutect2, varscan2
- CLCA4 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99760654; called by muse, varscan2
- CLCA4 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1420608283, COSV99760656; called by muse, mutect2, varscan2
- CLCA4 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99760660; called by muse, mutect2, varscan2
- CLCN1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs750408091, COSV100578242; called by muse, mutect2, varscan2
- CLCN1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143506735, COSV58372528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100578246; called by muse, mutect2, varscan2
- CLCN1 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100578249, COSV58372611; called by muse, mutect2, varscan2
- CLCN1 | c.2804C>T p.S935F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100578250; called by muse, mutect2, varscan2
- CLDN6 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559934937, COSV100172251; called by muse, mutect2, varscan2
- CLDND1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100360763; called by muse, mutect2, varscan2
- CLEC3A | c.476C>T p.S159F (on ENST00000651443; = p.S150F on NM_005752.6) | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV55220997; called by muse, mutect2, varscan2
- CLEC4F | c.826A>C p.N276H | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as COSV99713848; called by muse, mutect2, varscan2
- CLEC4F | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.32); catalogued as COSV99713672, COSV99713850; called by muse, mutect2, varscan2
- CLEC5A | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 40/82 reads (49%) | catalogued as COSV101407787; called by muse, mutect2, varscan2
- CLEC5A | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396684; called by muse, varscan2
- CLMP | c.515A>T p.K172I | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101507417; called by muse, mutect2, varscan2
- CMKLR1 | c.916A>T p.I306F (on ENST00000312143 / NM_001142344.2; = p.I304F on NM_004072.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100379523; called by muse, mutect2, varscan2
- CMYA5 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV101484182; called by muse, mutect2, varscan2
- CMYA5 | c.6289C>T p.P2097S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV71409139; called by muse, mutect2, varscan2
- CNBP | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV101421520; called by muse, mutect2, varscan2
- CNGA1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.154); catalogued as COSV100652277; called by muse, mutect2, varscan2
- CNGB1 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs768947322, COSV99204295; called by muse, mutect2, varscan2
- CNGB1 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV99204318; called by muse, mutect2, varscan2
- CNMD | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV100937237, COSV65034217; called by muse, mutect2, varscan2
- CNR2 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100991514; called by muse, mutect2, varscan2
- CNTN1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751625; called by muse, mutect2, varscan2
- CNTNAP2 | c.497G>A p.W166* | Nonsense Mutation (SNP) | VAF 55/112 reads (49%) | catalogued as COSV62170701; called by muse, mutect2, varscan2
- CNTNAP2 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1186551916, COSV62252736; called by muse, mutect2, varscan2
- CNTNAP2 | c.3464G>A p.G1155E | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62164446; called by muse, mutect2, varscan2
- CNTNAP5 | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV101443796, COSV70487379; called by muse, mutect2, varscan2
- CNTNAP5 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs765295281, COSV70502693; called by muse, mutect2, varscan2
- CNTNAP5 | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285313207, COSV101442888, COSV101443256; called by muse, mutect2, varscan2
- CNTNAP5 | c.3857C>T p.S1286F | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV70494464; called by muse, mutect2, varscan2
- COBL | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs532457394, COSV54348741; called by muse, mutect2, varscan2
- COBL | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.545); catalogued as COSV54339433; called by muse, mutect2, varscan2
- COL10A1 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV99684320; called by muse, mutect2, varscan2
- COL11A1 | c.2864G>A p.G955E | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62175422; called by muse, mutect2, varscan2
- COL11A1 | c.2228A>G p.E743G | Missense Mutation (SNP) | VAF 120/168 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100617341, COSV62191348; called by muse, mutect2, varscan2
- COL11A1 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT tolerated (0.57); PolyPhen benign (0.067); catalogued as COSV62178371, COSV62180680; called by muse, mutect2, varscan2
- COL12A1 | c.8870G>A p.G2957E | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100486232; called by muse, mutect2, varscan2
- COL12A1 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV59392176; called by muse, mutect2, varscan2
- COL14A1 | c.3793C>T p.H1265Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV99919876; called by muse, mutect2, varscan2
- COL14A1 | c.4687G>A p.G1563R | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs1213141280, COSV99919834; called by muse, mutect2, varscan2
- COL15A1 | c.3988C>T p.H1330Y | Missense Mutation (SNP) | VAF 176/216 reads (81%) | SIFT tolerated (0.52); PolyPhen benign (0.358); catalogued as rs1398406568, COSV100897850; called by muse, mutect2, varscan2
- COL19A1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100506816, COSV100506923; called by muse, mutect2
- COL1A1 | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99867669; called by muse, mutect2, varscan2
- COL1A1 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99867672; called by muse, mutect2, varscan2
- COL20A1 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1414539320, COSV100490896; called by muse, mutect2, varscan2
- COL21A1 | c.2546G>A p.G849E | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99779335; called by muse, mutect2, varscan2
- COL21A1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55156309; called by muse, mutect2, varscan2
- COL22A1 | c.3764G>A p.G1255E | Missense Mutation (SNP) | VAF 271/442 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279296, COSV57358947; called by muse, mutect2, varscan2
- COL23A1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.246); catalogued as COSV101179307; called by muse, mutect2, varscan2
- COL24A1 | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775541179, COSV100993601; called by muse, mutect2, varscan2
- COL24A1 | c.1942G>A p.G648R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100993602; called by muse, mutect2, varscan2
- COL27A1 | c.5270C>T p.S1757F | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100621131; called by muse, mutect2, varscan2
- COL2A1 | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs570320774, COSV100476957; called by mutect2, varscan2
- COL3A1 | c.2968G>A p.G990R | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483352; called by muse, mutect2, varscan2
- COL3A1 | c.3637G>A p.A1213T | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100483353, COSV58586579; called by muse, mutect2, varscan2
- COL4A3 | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101170399; called by mutect2, varscan2
- COL4A3 | c.2174A>T p.K725I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV101170400, COSV101170637; called by muse, varscan2
- COL4A3 | c.4826G>A p.R1609Q | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1380878336, COSV67414252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A4 | c.3475C>T p.P1159S | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0.425); catalogued as rs1395462000, COSV100307272; called by muse, mutect2, varscan2
- COL4A4 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61634964; called by muse, mutect2, varscan2
- COL4A5 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100088566; called by muse, mutect2, varscan2
- COL4A5 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as CD115550, COSV60364536; called by muse, mutect2, varscan2
- COL4A6 | c.4864G>A p.G1622S | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564508; called by muse, mutect2, varscan2
- COL4A6 | c.2602C>G p.L868V | Missense Mutation (SNP) | VAF 91/112 reads (81%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.81); catalogued as COSV100564510; called by muse, mutect2, varscan2
- COL5A1 | c.4354C>T p.P1452S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100880167; called by muse, mutect2, varscan2
- COL5A2 | c.3563G>A p.G1188E | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66416784; called by muse, varscan2
- COL5A3 | c.4844G>A p.G1615E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99319267; called by muse, varscan2
- COL5A3 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99319270; called by muse, mutect2, varscan2
- COL5A3 | c.3343G>A p.G1115R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99319272; called by muse, mutect2
- COL5A3 | c.2247G>A p.G749= | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99319276; called by muse, mutect2, varscan2
- COL5A3 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99319278; called by muse, mutect2, varscan2
- COL6A3 | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.59); catalogued as rs113538665, COSV55107615; called by muse, mutect2, varscan2
- COL7A1 | c.6806G>A p.G2269E | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60403973; called by muse, mutect2, varscan2
- COL7A1 | c.4484G>A p.G1495D | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100096873; called by muse, mutect2, varscan2
- COL8A2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.646); catalogued as rs776813844, COSV57442924; called by muse, varscan2
- COL9A1 | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100295123; called by muse, mutect2, varscan2
- COL9A3 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191608453, COSV59654141; called by muse, mutect2, varscan2
- COLEC10 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753723366, COSV60521464; called by muse, mutect2, varscan2
- CPA2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55979431, COSV99743725; called by muse, mutect2, varscan2
- CPA6 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.243); catalogued as rs765453517, COSV99914003; called by muse, mutect2, varscan2
- CPAMD8 | c.3919G>A p.D1307N (on ENST00000651564; = p.D1260N on NM_015692.5) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs776066399, COSV71596723; called by muse, mutect2, varscan2
- CPB1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs150860615, COSV99294138; called by muse, mutect2, varscan2
- CPN2 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs753983327, COSV100103176; called by muse, mutect2, varscan2
- CPO | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99786570; called by muse, mutect2, varscan2
- CPZ | c.1780G>A p.G594R (on ENST00000360986 / NM_001014447.3; = p.G583R on NM_003652.3) | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100249072; called by muse, mutect2, varscan2
- CR1L | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV54322614, COSV99687669; called by muse, mutect2, varscan2
- CR1L | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 27/168 reads (16%) | catalogued as COSV54322326; called by muse, mutect2, varscan2
- CR2 | c.2699G>A p.W900* | Nonsense Mutation (SNP) | VAF 28/45 reads (62%) | catalogued as COSV65509011; called by muse, mutect2, varscan2
- CRACDL | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101194083; called by muse, mutect2, varscan2
- CRB1 | c.3206G>A p.G1069E | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100957972; called by muse, varscan2
- CREB3L1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99915167; called by muse, mutect2, varscan2
- CREB3L2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV57796816; called by muse, mutect2, varscan2
- CREB3L3 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV50253092; called by muse, mutect2, varscan2
- CREB3L4 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99665785; called by muse, mutect2, varscan2
- CREBBP | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as COSV52119166; called by muse, mutect2, varscan2
- CROCC | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); catalogued as rs1285307280, COSV100978016; called by muse, mutect2, varscan2
- CRYBG1 | c.5096G>A p.G1699E | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64813252; called by muse, mutect2, varscan2
- CRYBG2 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.053); catalogued as COSV57483418; called by muse, varscan2
- CRYBG2 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.267); catalogued as COSV57489467; called by muse, mutect2, varscan2
- CRYGB | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV53680520; called by muse, mutect2, varscan2
- CSDE1 | c.893C>T p.P298L (on ENST00000358528 / NM_001007553.3; = p.P267L on NM_007158.6) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99795392; called by muse, mutect2, varscan2
- CSF3R | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV100117939; called by muse, mutect2, varscan2
- CSMD1 | c.6202G>A p.D2068N (on ENST00000520002; = p.D2067N on NM_033225.6) | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768275953, COSV100150597; called by muse, mutect2, varscan2
- CSMD2 | c.9539G>A p.G3180E | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99592296; called by muse, mutect2, varscan2
- CSMD2 | c.5309C>T p.S1770L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs996980083, COSV99592299; called by muse, mutect2
- CSMD2 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411334338, COSV99592303; called by muse, mutect2, varscan2
- CSMD3 | c.10937G>A p.G3646E (on ENST00000297405 / NM_001363185.1; = p.G3477E on NM_052900.3) | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99839656; called by muse, varscan2
- CSMD3 | c.10103G>A p.G3368E (on ENST00000297405 / NM_001363185.1; = p.G3199E on NM_052900.3) | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV52118368; called by muse, mutect2, varscan2
- CSN3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100515357; called by muse, mutect2, varscan2
- CSTF2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880791; called by muse, mutect2, varscan2
- CTAGE6 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV101417863; called by muse, mutect2, varscan2
- CTNNA3 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs749493440, COSV65556605; called by muse, mutect2, varscan2
- CTNND2 | c.3616C>T p.P1206S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV58915994; called by muse, mutect2, varscan2
- CTNND2 | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100478707; called by muse, mutect2, varscan2
- CTR9 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100797398; called by muse, mutect2, varscan2
- CTRC | c.163T>G p.W55G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101036398; called by muse, mutect2
- CTSE | c.159G>C p.M53I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.135); catalogued as COSV100733685; called by muse, mutect2, varscan2
- CTSG | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99361600; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1442122914, COSV54744771; called by muse, mutect2, varscan2
- CUBN | c.7897C>T p.L2633F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100913067; called by muse, mutect2, varscan2
- CUBN | c.2842C>T p.H948Y | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100913068; called by muse, mutect2, varscan2
- CUBN | c.2318C>T p.T773I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs200658389, COSV100913070; called by muse, mutect2, varscan2
- CUL9 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.715); catalogued as COSV99335665; called by muse, mutect2, varscan2
- CUX2 | c.222G>A p.E74= | Splice Region (SNP) | VAF 44/60 reads (73%) | catalogued as COSV99920107; called by muse, mutect2, varscan2
- CWC25 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs1485454181; called by muse, mutect2, varscan2
- CYFIP2 | c.3499G>A p.G1167R (on ENST00000616178 / NM_001291722.2; = p.G1142R on NM_014376.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs1217061527, COSV100557366; called by muse, mutect2, varscan2
- CYLC1 | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV61415823; called by muse, mutect2, varscan2
- CYP11B2 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs372167175; called by muse, mutect2, varscan2
- CYP27C1 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100079918; called by muse, mutect2, varscan2
- CYP2C8 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100987967; called by muse, mutect2, varscan2
- CYP2C8 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV64877011; called by muse, mutect2, varscan2
- CYP2C9 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV53248326; called by muse, mutect2, varscan2
- CYP3A7 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1457258221, COSV100312747; called by muse, mutect2, varscan2
- CYP4A22 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs375999051; called by muse, mutect2
- CYP4F8 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161998646, COSV100358168; called by muse, mutect2, varscan2
- CYP8B1 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.687); catalogued as COSV100296221; called by muse, varscan2
- CYTH4 | c.770T>G p.F257C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99958039; called by muse, mutect2, varscan2
- DAAM1 | c.491T>C p.F164S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1370533873, COSV100658536; called by muse, mutect2, varscan2
- DAB1 | c.899C>T p.P300L (on ENST00000371231; = p.P267L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100976447; called by muse, mutect2
- DACH1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as rs1330298263, COSV57512070; called by muse, mutect2
- DACT1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV100241964; called by muse, mutect2, varscan2
- DCAF1 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1553632245, COSV100244638; called by muse, mutect2, varscan2
- DCAF4L1 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100295831; called by muse, mutect2, varscan2
- DCAF8L1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101491491; called by muse, mutect2, varscan2
- DCC | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 30/103 reads (29%) | catalogued as rs773315729, COSV71427767; called by muse, mutect2, varscan2
- DCLK3 | c.990A>C p.E330D | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV101374031; called by muse, mutect2, varscan2
- DCP1B | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99767674; called by muse, mutect2, varscan2
- DCX | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM010025, CM980533, COSV100576745, COSV57566845; called by muse, mutect2, varscan2
- DDN | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV100305282; called by muse, mutect2, varscan2
- DDO | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.828); catalogued as COSV64469712, COSV64470829; called by muse, mutect2, varscan2
- DDX31 | c.2035C>G p.H679D | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100936824; called by muse, mutect2, varscan2
- DDX60 | c.1606C>T p.H536Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101190537; called by muse, mutect2, varscan2
- DEFB118 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.193); catalogued as COSV53620573, COSV99489135, COSV99489262; called by muse, mutect2, varscan2
- DEFB127 | c.238A>T p.T80S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs764737803, COSV101213859; called by muse, mutect2, varscan2
- DENND2A | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1445459894, COSV99326472; called by muse, mutect2, varscan2
- DENND2C | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs779519005, COSV67924337; called by muse, mutect2, varscan2
- DENND2C | c.605A>C p.E202A | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.659); catalogued as COSV101283954; called by muse, mutect2, varscan2
- DENND2C | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs772944552, COSV67920142; called by muse, varscan2
- DEPDC1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs777754199, COSV100920217; called by muse, mutect2, varscan2
- DESI1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs770814598, COSV54353989; called by muse, mutect2, varscan2
- DGAT1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183942, COSV60048815; called by muse, mutect2, varscan2
- DGKD | c.1757C>T p.S586F (on ENST00000264057 / NM_152879.3; = p.S542F on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs866122524, COSV99896829; called by muse, mutect2, varscan2
- DHRS4L2 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100632556; called by muse, mutect2, varscan2
- DHRS7C | c.845C>T p.A282V (on ENST00000330255 / NM_001220493.2; = p.A281V on NM_001105571.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.094); catalogued as rs1290851787, COSV100364809; called by muse, mutect2, varscan2
- DIPK2B | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV101211689; called by muse, mutect2, varscan2
- DISP2 | c.3500C>T p.P1167L | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99140194; called by muse, mutect2, varscan2
- DISP3 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV99609277; called by muse, mutect2, varscan2
- DISP3 | c.2539C>T p.L847F | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53828845, COSV99609280; called by muse, mutect2, varscan2
- DISP3 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs377572784; called by muse, mutect2, varscan2
- DLC1 | c.3982T>G p.C1328G (on ENST00000276297 / NM_001348081.2; = p.C891G on NM_006094.5) | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.105); catalogued as COSV99364184; called by muse, mutect2, varscan2
- DLEC1 | c.1617C>G p.I539M | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1164771335, COSV100342891; called by muse, mutect2, varscan2
- DLEC1 | c.4136G>A p.G1379E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100342897; called by muse, mutect2, varscan2
- DLG2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV54678972; called by muse, mutect2, varscan2
- DLG5 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV64950296; called by muse, mutect2, varscan2
- DLGAP3 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV99332897; called by muse, mutect2, varscan2
- DLGAP3 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99332899; called by muse, mutect2, varscan2
- DLGAP3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as rs377339687; called by muse, mutect2, varscan2
- DLGAP3 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV99332901; called by muse, mutect2, varscan2
- DMBT1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.759); catalogued as COSV57539831; called by muse, mutect2, varscan2
- DMBT1 | c.7190C>T p.P2397L (on ENST00000338354 / NM_001377530.1; = p.P1640L on NM_004406.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs752965644, COSV100353528; called by muse, mutect2, varscan2
- DMGDH | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54866865; called by muse, mutect2, varscan2
- DMGDH | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV99669236; called by muse, varscan2
- DMRT3 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs147923658, COSV51903707; called by muse, mutect2, varscan2
- DMXL1 | c.6124C>T p.R2042C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750727596, COSV100224396; called by muse, mutect2
- DNAAF1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1029448507, COSV100533740; called by muse, mutect2
- DNAAF1 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV57576385; called by muse, mutect2, varscan2
- DNAH10 | c.12615A>G p.E4205= (on ENST00000409039; = p.E4144= on NM_207437.3) | Splice Region (SNP) | VAF 9/51 reads (18%) | catalogued as COSV101292413; called by muse, mutect2, varscan2
- DNAH11 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs751244693, COSV60964128, COSV60985826; called by muse, mutect2, varscan2
- DNAH11 | c.12994G>A p.V4332I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV100179787; called by muse, mutect2, varscan2
- DNAH17 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1434314562, COSV67755857; called by muse, mutect2, varscan2
- DNAH2 | c.5659C>T p.H1887Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101209484; called by muse, mutect2, varscan2
- DNAH2 | c.7394G>A p.R2465Q | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777043389, COSV66719898; called by muse, mutect2, varscan2
- DNAH2 | c.10789G>A p.E3597K | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV101209485; called by muse, mutect2, varscan2
- DNAH3 | c.6199G>A p.E2067K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.58); PolyPhen benign (0.17); catalogued as COSV54538456; called by muse, mutect2, varscan2
- DNAH3 | c.4861C>T p.P1621S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99768857; called by muse, mutect2, varscan2
- DNAH3 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs770778993, COSV99768862; called by muse, mutect2, varscan2
- DNAH5 | c.12886G>A p.D4296N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV99451612; called by muse, mutect2, varscan2
- DNAH5 | c.8328G>A p.M2776I | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99451617; called by muse, mutect2, varscan2
- DNAH5 | c.6274G>A p.E2092K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs865876907, COSV54246857; called by muse, mutect2, varscan2
- DNAH5 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs1470329012, COSV54210192, COSV54243654; called by muse, mutect2, varscan2
- DNAH6 | c.1960C>T p.H654Y | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.424); catalogued as rs1244574349, COSV52869660; called by muse, mutect2, varscan2
- DNAH7 | c.9518C>T p.S3173F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1247678643, COSV100416136; called by muse, mutect2, varscan2
- DNAH7 | c.7073C>T p.A2358V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.349); catalogued as COSV100416137; called by muse, mutect2, varscan2
- DNAH7 | c.6240G>A p.M2080I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs769474761, COSV56783391, COSV56794633; called by muse, mutect2, varscan2
- DNAH7 | c.4906G>A p.E1636K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as rs866583990, COSV100416139; called by muse, mutect2, varscan2
- DNAH7 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV100416144; called by muse, mutect2, varscan2
- DNAH8 | c.2116C>T p.Q706* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100546279, COSV59443708; called by muse, mutect2, varscan2
- DNAH8 | c.2849G>A p.G950E | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59486923; called by muse, mutect2, varscan2
- DNAH9 | c.3487G>A p.D1163N | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV99306778; called by muse, mutect2, varscan2
- DNAH9 | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99306779; called by muse, mutect2, varscan2
- DNAH9 | c.4742G>A p.G1581D | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1388504238, COSV99306781; called by muse, mutect2, varscan2
- DNAH9 | c.6164G>A p.G2055E | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52347411, COSV99303230; called by muse, mutect2, varscan2
- DNAH9 | c.8041G>A p.D2681N | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145103593, COSV52339268, COSV52382416; called by muse, mutect2, varscan2
- DNAI2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.177); catalogued as rs752440806, COSV56761525; called by muse, mutect2, varscan2
- DNAJC21 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV100331509; called by muse, varscan2
- DNM3 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1302274033, COSV100798432; called by muse, mutect2, varscan2
- DNTTIP1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs767080264, COSV101009992, COSV65460932; called by muse, mutect2, varscan2
- DOCK3 | c.1377G>A p.K459= | Splice Region (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99813470; called by muse, mutect2, varscan2
- DOCK3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1275095125, COSV99813472; called by muse, mutect2, varscan2
- DOCK3 | c.3770C>T p.A1257V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99813477; called by muse, mutect2, varscan2
- DOCK4 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs778892000, COSV101455624; called by muse, mutect2, varscan2
- DOCK6 | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as rs1275457276, COSV99626086; called by muse, mutect2, varscan2
- DOT1L | c.1926C>T p.I642= | Splice Region (SNP) | VAF 22/77 reads (29%) | catalogued as COSV101288725; called by muse, mutect2, varscan2
- DPEP2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV99263168; called by muse, mutect2, varscan2
- DPPA2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101524784; called by muse, mutect2, varscan2
- DPY19L2 | c.1401T>G p.Y467* | Nonsense Mutation (SNP) | VAF 44/85 reads (52%) | catalogued as COSV100116862; called by muse, varscan2
- DPYD | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64603724; called by muse, mutect2, varscan2
- DPYD | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100929219; called by muse, mutect2, varscan2
- DSC1 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99937876; called by muse, mutect2, varscan2
- DSE | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.528); catalogued as COSV100528675; called by muse, mutect2, varscan2
- DSG2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99853304; called by muse, mutect2, varscan2
- DSG2 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs756081987, COSV99853306; called by muse, mutect2, varscan2
- DSG2 | c.1963C>T p.H655Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99853308; called by muse, mutect2, varscan2
- DSG2 | c.3067C>T p.L1023F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99853309; called by muse, mutect2, varscan2
- DSG3 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99934431; called by muse, mutect2, varscan2
- DSG3 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.604); catalogued as COSV57124824; called by muse, mutect2, varscan2
- DSG4 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 49/128 reads (38%) | catalogued as COSV100356120; called by muse, mutect2, varscan2
- DSP | c.1417C>T p.Q473* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV65791735; called by muse, mutect2, varscan2
- DSP | c.5856G>C p.E1952D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as COSV101131474; called by muse, mutect2, varscan2
- DSPP | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99217622; called by muse, mutect2, varscan2
- DSPP | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as COSV99216799; called by muse, mutect2, varscan2
- DUOX1 | c.2182A>T p.N728Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100368169; called by muse, mutect2, varscan2
- DUOX1 | c.2420T>A p.F807Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100368171; called by muse, mutect2, varscan2
- DUOX2 | c.2655-1G>A p.X885_splice | Splice Site (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101199817; called by muse, mutect2
- DUSP3 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV99871505; called by muse, mutect2, varscan2
- DYNC1I1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61458769; called by muse, mutect2, varscan2
- DYNC2H1 | c.11009C>T p.S3670F | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100519040; called by muse, mutect2, varscan2
- DYNLRB2 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200686705, COSV100009631, COSV100009796; called by muse, mutect2, varscan2
- DYNLRB2 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.94); PolyPhen benign (0.055); catalogued as COSV100009798; called by muse, mutect2, varscan2
- DYSF | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99248728; called by muse, mutect2, varscan2
- DYSF | c.4969G>A p.E1657K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368142107, CM070072, COSV50491951; called by muse, mutect2, varscan2
- DYSF | c.5620C>T p.P1874S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV50593636; called by muse, mutect2, varscan2
- DYSF | c.5771C>T p.S1924F | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs777035277, COSV99248253; called by muse, mutect2, varscan2
- DZIP1 | c.2036C>T p.P679L (on ENST00000347108; = p.P660L on NM_014934.5) | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100714139; called by muse, mutect2, varscan2
- E2F6 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs754190161, COSV100215377; called by muse, mutect2, varscan2
- E2F7 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100523666; called by muse, mutect2, varscan2
- EBF2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369154726; called by muse, mutect2, varscan2
- ECPAS | c.4415C>T p.A1472V | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1564497867, COSV99398753; called by muse, mutect2, varscan2
- ECPAS | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99398754; called by muse, mutect2, varscan2
- EDIL3 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV56916147; called by muse, mutect2, varscan2
- EDIL3 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99677680; called by muse, mutect2, varscan2
- EDIL3 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56891188, COSV99677683; called by muse, mutect2, varscan2
- EDNRA | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100163497; called by muse, mutect2, varscan2
- EFHC1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs867304706, COSV100932087; called by muse, mutect2, varscan2
- EFL1 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99187638; called by muse, mutect2, varscan2
- EFS | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as COSV99391680; called by muse, mutect2, varscan2
- EGF | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.036); catalogued as COSV99491154; called by muse, mutect2, varscan2
- EGF | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372658291, COSV99491156; called by muse, mutect2, varscan2
- EGF | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV99491157; called by muse, mutect2
- EGFL6 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63633480, COSV63635058; called by muse, mutect2, varscan2
- EGFLAM | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs369346695, COSV59296529; called by muse, mutect2, varscan2
- EGFLAM | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV59297844; called by muse, mutect2, varscan2
- EGFLAM | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1461002865, COSV100380490; called by muse, mutect2
- EGR1 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99525508; called by muse, mutect2, varscan2
- EHBP1 | c.1862T>C p.V621A | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.497); catalogued as rs1240945757, COSV50446028; called by muse, mutect2, varscan2
- EHD1 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100277165; called by muse, mutect2, varscan2
- EHMT1 | c.3071C>T p.P1024L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV101509714; called by muse, mutect2, varscan2
- EIF2AK3 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV57551232; called by muse, mutect2, varscan2
- EIF4B | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs1228877549, COSV50403083; called by muse, mutect2, varscan2
- EIPR1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1219838910, COSV66130954; called by muse, mutect2, varscan2
- ELAPOR2 | c.2735C>T p.S912F (on ENST00000450689 / NM_001142749.3; = p.S745F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs749291023, COSV51885344, COSV99789101; called by muse, mutect2, varscan2
- ELMO1 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165102; called by muse, mutect2, varscan2
- ELMO1 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs1486846711, COSV100164785, COSV60322689; called by muse, mutect2, varscan2
- ELMO1 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100165103; called by muse, mutect2, varscan2
- ELOA2 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1180767750, COSV99797166; called by muse, mutect2, varscan2
- ELOA2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs750506707, COSV55310525; called by muse, mutect2, varscan2
- ELOVL5 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100439757; called by muse, mutect2, varscan2
- ELSPBP1 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1568409110, COSV100353690; called by muse, mutect2, varscan2
- EMB | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as rs375679309; called by muse, mutect2, varscan2
- EMC4 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV99272719; called by muse, mutect2
- EML1 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV99215267; called by muse, mutect2, varscan2
- EML1 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV51752380; called by muse, mutect2, varscan2
- EML1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs753712572, COSV51754202, COSV51754845; called by muse, mutect2, varscan2
- EML5 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV100715924; called by muse, mutect2, varscan2
- EML5 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100715925; called by muse, mutect2, varscan2
3,254 further variants in this file (1,828 protein-altering or splice-affecting, 1,309 silent, 117 other) are not listed here.
